Somatic mutation profile of tumor specimen TCGA-HT-7470-01A (aliquot TCGA-HT-7470-01A-12D-2086-08) from TCGA case TCGA-HT-7470, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 37.3 years (13,611 days).
Specimen TCGA-HT-7470-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddc3d0a4-6d7e-495f-9ee6-8f9cb23fb041.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7470-10A (Blood Derived Normal), aliquot TCGA-HT-7470-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30d90251-9dbf-4f2c-8fef-2e47a9dee153

The open-access MAF lists 44 somatic variants for this specimen: 35 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 29, Silent 9, Nonsense Mutation 3, Frame Shift Ins 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.394C>A p.R132S | Missense Mutation (SNP) | VAF 34/134 reads (25%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 28/41 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGL | c.1910C>T p.A637V | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1488937187, COSV54057215; called by muse, mutect2, varscan2
- AKAP4 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201625510, COSV62075332; called by muse, mutect2, varscan2
- ANKRD11 | c.4846G>A p.G1616R | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs1361881680, COSV56369304; called by muse, mutect2, varscan2
- CAPSL | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs369979397, COSV101274195; called by muse, mutect2, varscan2
- CEPT1 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 7/136 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1197932725, COSV62958662; called by muse, mutect2
- CFH | c.161C>A p.P54H | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62778582, COSV62778782; called by muse, mutect2
- COL19A1 | c.2449A>G p.I817V | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59584297; called by muse, mutect2, varscan2
- CUBN | c.5174G>C p.G1725A | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as COSV64724651; called by muse, mutect2, varscan2
- DOP1A | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 25/85 reads (29%) | catalogued as COSV52716060; called by muse, mutect2, varscan2
- ERCC4 | c.1831G>A p.G611R | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.808); catalogued as rs749814308, COSV61313554; called by muse, mutect2, varscan2
- FOXB2 | c.878C>T p.S293F | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV65023895; called by muse, mutect2, varscan2
- GPR149 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV67669343; called by muse, mutect2, varscan2
- IGHA1 | c.998C>T p.A333V | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs370272298; called by muse, mutect2, varscan2
- KCNH8 | c.3157G>T p.G1053C | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60473889; called by muse, mutect2
- LRRTM4 | c.1720A>G p.T574A | Missense Mutation (SNP) | VAF 56/235 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs1283521143, COSV69174218; called by muse, mutect2, varscan2
- MICAL1 | c.1336A>G p.T446A | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV62195608; called by muse, mutect2
- MYO19 | c.1091G>A p.R364Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs532960922; called by muse, mutect2, varscan2
- NOTCH1 | c.1442G>T p.G481V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53027059, COSV53057342; called by muse, mutect2
- OR52E8 | c.669T>G p.Y223* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV66211269; called by muse, mutect2, varscan2
- PPP1R12C | c.1682A>C p.Q561P | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54739561; called by muse, mutect2, varscan2
- PTPRB | c.3743A>G p.D1248G | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.031); catalogued as COSV54250629; called by muse, mutect2, varscan2
- RNF145 | c.292A>G p.R98G (on ENST00000424310 / NM_001199383.2; = p.R126G on NM_144726.2) | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV50870885; called by muse, mutect2, varscan2
- RYR2 | c.10183C>T p.L3395F | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63707322; called by muse, mutect2, varscan2
- SNX19 | c.2704C>T p.Q902* | Nonsense Mutation (SNP) | VAF 48/296 reads (16%) | catalogued as rs1037731153, COSV56288137; called by muse, varscan2
- TCHH | c.4789T>A p.F1597I | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV64277194; called by muse, mutect2, varscan2
- TMC3 | c.2992G>A p.E998K | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV63924296; called by muse, mutect2
- TRAPPC11 | c.3175T>G p.S1059A | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.875); catalogued as COSV58218572; called by muse, mutect2, varscan2
- TRPM8 | c.2990A>G p.Q997R | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV61223709; called by muse, mutect2, varscan2
- ZNF638 | c.1402A>C p.I468L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.891); catalogued as COSV52494611; called by muse, mutect2, varscan2
- ANXA6 | c.1926_1927insCG p.E643Rfs*21 | Frame Shift Ins (INS) | VAF 6/45 reads (13%) | called by mutect2, pindel*
- ATRX | c.5392dup p.R1798Kfs*12 | Frame Shift Ins (INS) | VAF 62/128 reads (48%) | called by mutect2, pindel, varscan2
- PEX1 | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); called by muse, mutect2
- ZW10 | c.1394del p.N465Ifs*19 | Frame Shift Del (DEL) | VAF 47/189 reads (25%) | called by mutect2, pindel, varscan2
- ABI3BP | c.2400A>G p.Q800= | Silent (SNP) | VAF 22/170 reads (13%) | catalogued as COSV52548256; called by muse, mutect2, varscan2
- FAM153B | c.849C>A p.A283= (on ENST00000253490; = p.A206= on NM_001265615.1) | Silent (SNP) | VAF 28/353 reads (8%) | catalogued as COSV53688127; called by muse, mutect2
- FCGBP | c.11982C>T p.S3994= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as rs370196020; called by muse, mutect2, varscan2
- HTR3B | c.426C>A p.T142= | Silent (SNP) | VAF 19/211 reads (9%) | catalogued as COSV52747037; called by muse, mutect2
- LRP4 | c.4632C>T p.L1544= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV66138066; called by muse, mutect2, varscan2
- PRSS22 | c.225C>T p.C75= | Silent (SNP) | VAF 17/110 reads (15%) | catalogued as rs200127582, COSV50721757; called by muse, mutect2, varscan2
- RHBDF1 | c.1344C>T p.Y448= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as COSV51957541; called by muse, mutect2
- SHF | c.384A>G p.P128= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV52052078; called by muse, mutect2, varscan2
- STATH | c.177A>G p.Q59= | Silent (SNP) | VAF 45/200 reads (23%) | catalogued as COSV55894131; called by muse, mutect2, varscan2
